Gene-level copy-number profile of tumor specimen TCGA-E7-A97Q-01A from TCGA case TCGA-E7-A97Q, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Bladder, NOS; AJCC pathologic stage: Stage IV; Tumor grade: High Grade; Age at diagnosis: 60.9 years (22,249 days).
Specimen TCGA-E7-A97Q-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-BLCA.9429c2b9-a17f-41e7-aa57-0759090d3e7e.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-E7-A97Q-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 807 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/d9ba33d0-e748-403c-8eff-6b9e31d0af32

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 28; copy number 1: 5; copy number 2: 17,382; copy number 3: 13,013; copy number 4: 15,351; copy number 5: 8,602; copy number 6: 2,446; copy number 7: 627; copy number 8: 1,708; copy number 9: 307; copy number 10: 40; copy number 11: 60; copy number 12: 146; copy number 15: 26; copy number 22: 14; copy number 23: 1; copy number 27: 60.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-E7-A97Q-01A-11D-A38F-01): tumor purity 0.65, ploidy 3.65, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 28 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:155,089,439–155,089,538, 1 gene: RNU6-1001P.
- chr2:212,426,263–212,426,360, 1 gene: MIR548F2.
- chr12:10,824,960–11,171,608, 1 gene (within-gene range 0–2): PRH1.
- chr12:10,845,849–11,310,436, 25 genes: PRR4, AC018630.4, AC006518.2, TAS2R13, PRH2, TAS2R14, TAS2R15P, TAS2R50, TAS2R20, TAS2R19, TAS2R31, TAS2R63P, TAS2R46, TAS2R64P, TAS2R43, AC018630.1, TAS2R30, AC134349.2, AC134349.1, SMIM10L1, TAS2R42, AC244131.1, AC244131.2, PRB3, PRB4.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 14,035 genes in 34 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:57,598–6,784,843, 257 genes, copy number 5 (broad region; genes not listed).
- chr1:6,834,333–7,014,279, 2 genes, copy number 5: AL590128.1, AL512330.1.
- chr1:42,733,093–43,454,247, 37 genes, copy number 5 (within-gene range 4–5): CLDN19, P3H1, C1orf50, AC098484.3, AC098484.1, TMEM269, SVBP, ERMAP, AL512353.1, ZNF691, AL512353.2, MKRN8P, ATP6V1E1P1, SLC2A1, ATP6V0CP4, SLC2A1-AS1, AC099795.1, RNU6-880P, U6, AL161637.1, FAM183A, EBNA1BP2, MIR6733, CFAP57, RNA5SP46, TMEM125, C1orf210, TIE1, MPL, AL139289.2, AL139289.1, CDC20, ELOVL1, MIR6734, MED8, MED8-AS1, SZT2.
- chr1:111,483,348–111,563,962, 1 gene, copy number 5 (within-gene range 4–5): TMIGD3.
- chr1:111,542,218–192,957,713, 1,626 genes, copy number 5 (broad region; genes not listed).
- chr1:193,090,866–244,971,088, 1,058 genes, copy number 5 (broad region; genes not listed).
- chr1:245,749,342–248,919,946, 136 genes, copy number 5 (broad region; genes not listed).
- chr2:38,814–98,313,299, 1,785 genes, copy number 5–7 (within-gene range 2–7) (broad region; genes not listed).
- chr2:106,063,246–108,687,246, 52 genes, copy number 6 (within-gene range 2–6): ECRG4, UXS1, AC018878.1, AC092106.1, RPL22P10, SRSF3P4, RPS21P2, RPL27AP4, ILRUNP1, AC114755.1, ANAPC1P6, PLGLA, RGPD3, AC097527.1, CD8B2, AC108868.2, AC108868.1, EEF1A1P12, ST6GAL2, ST6GAL2-IT1, AC016994.1, AC005040.2, PPP1R2P5, AC005040.1, LINC01789, AC096669.1, LINC01885, LINC01886, AC064869.1, GACAT1, RGPD4-AS1, RGPD4, AC009963.2, AC009963.1, RPL22P8, SRSF3P5, SLC5A7, LINC01593, ACTP1, LINC01594, SETD6P1, SULT1C3, WASF1P1, SULT1C2, SULT1C2P2, SULT1C2P1, GMCL1P2, SULT1C4, SMIM12P1, GCC2, GCC2-AS1, LIMS1.
- chr2:111,607,841–114,420,302, 90 genes, copy number 5 (broad region; genes not listed).
- chr3:11,745–39,096,671, 533 genes, copy number 6–22 (within-gene range 2–22) (broad region; genes not listed).
- chr3:93,843,764–100,456,319, 95 genes, copy number 5 (broad region; genes not listed).
- chr3:117,672,154–117,997,592, 1 gene, copy number 5 (within-gene range 4–5): AC092691.1.
- chr3:117,719,859–119,636,150, 23 genes, copy number 5: AC092691.3, AC068633.1, AC068633.2, IGSF11, IGSF11-AS1, TEX55, AC083800.1, UPK1B, B4GALT4, B4GALT4-AS1, ARHGAP31, RPS26P21, ARHGAP31-AS1, RNU6-1127P, TMEM39A, POGLUT1, AC073352.1, TIMMDC1, CD80, AC073352.2, ADPRH, PLA1A, RPL10P7.
- chr5:50,396,192–51,428,427, 19 genes, copy number 6: EMB, AC112187.2, AC112187.1, AC112187.3, PARP8, AC022441.1, AC022441.3, AC022441.2, AC008808.2, LINC02106, AC008808.1, RNU6-480P, AC091834.1, RNU6-1296P, AC026798.1, AC010478.1, ISL1, HMGB1P47, AC091860.1.
- chr5:51,451,158–51,462,089, 1 gene, copy number 6: AC091860.2.
- chr7:70,972–63,843,505, 1,122 genes, copy number 5 (broad region; genes not listed).
- chr8:34,784,028–35,093,509, 3 genes, copy number 12: LINC01288, AC087343.1, AC099685.1.
- chr8:35,254,344–35,256,605, 1 gene, copy number 23: AC090740.1.
- chr8:36,784,324–36,936,125, 1 gene, copy number 22 (within-gene range 2–22): KCNU1.
- chr8:36,887,456–145,066,685, 1,707 genes, copy number 6–27 (broad region; genes not listed).
- chr10:4,871,901–5,135,226, 9 genes, copy number 5 (within-gene range 4–5): AKR1C6P, U8, AKR1C1, AKR1C2, AL391427.1, U8, AKR1C3, U8, AKR1C5P.
- chr10:11,395,808–12,043,170, 9 genes, copy number 5 (within-gene range 4–5): AC026887.1, USP6NL, AL512631.2, AL512631.1, ECHDC3, PROSER2, PROSER2-AS1, UPF2, RNU6-1095P.
- chr10:69,994,276–70,447,951, 14 genes, copy number 6: LINC02636, MACROH2A2, AIFM2, TYSND1, SAR1A, CALM2P2, RPS25P9, PPA1, NPFFR1, LRRC20, CEP57L1P1, EIF4EBP2, NODAL, AC022532.1.
- chr10:126,424,997–126,798,708, 1 gene, copy number 6 (within-gene range 4–6): C10orf90.
- chr10:126,779,702–133,761,125, 124 genes, copy number 6 (broad region; genes not listed).
- chr11:54,591,480–103,479,863, 1,492 genes, copy number 5–8 (broad region; genes not listed).
- chr13:18,467,172–114,337,626, 1,391 genes, copy number 6–8 (broad region; genes not listed).
- chr14:91,271,323–91,780,707, 11 genes, copy number 5 (within-gene range 3–5): CCDC88C, AL133153.2, AL133153.1, PPP4R3A, AL133373.2, AL133373.3, CATSPERB, POLR3GP1, NANOGP7, AL121839.1, U3.
- chr16:66,942,712–90,222,851, 710 genes, copy number 5 (broad region; genes not listed).
- chr18:23,957,754–23,982,556, 1 gene, copy number 6: AC010754.1.
- chr18:23,994,213–24,015,339, 1 gene, copy number 6: TTC39C-AS1.
- chr19:54,160,108–57,916,591, 264 genes, copy number 5–8 (within-gene range 2–8) (broad region; genes not listed).
- chr20:87,250–64,313,132, 1,458 genes, copy number 5–8 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 5. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
